Somatic mutation profile of tumor specimen MMRF_2829_1_BM_CD138pos (aliquot MMRF_2829_1_BM_CD138pos_T1_KHS5U_L16557) from MMRF case MMRF_2829, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.9 years (21,130 days).
Specimen MMRF_2829_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3266d48-7b5d-4ca5-a6da-8ac4bece3f81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2829_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2829_1_PB_WBC_C2_KHS5U_L16604; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9010bd3-42a7-41b9-9f2e-a07d841f88f4

The open-access MAF lists 13 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 7, Silent 2, Intron 2, Missense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SEL1L3 | c.44A>G p.Q15R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEG3 | c.4560C>T p.F1520= | Silent (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
- PRDM2 | c.4209T>C p.L1403= | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- CLNK | c.*1235T>C | 3'UTR (SNP) | VAF 5/80 reads (6%) | catalogued as rs1389574791; called by muse, mutect2
- EEF2KMT | c.*1137T>C | 3'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- EMX1 | c.*233G>A | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- FGFR2 | c.*1185A>T | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- MARCHF3 | c.*428T>C | 3'UTR (SNP) | VAF 4/68 reads (6%) | catalogued as rs1409820615; called by muse, mutect2
- PTPRN2 | c.2344+4426A>T | Intron (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- RABL2A | c.217+50G>T | Intron (SNP) | VAF 8/59 reads (14%) | called by mutect2, varscan2
- SNORD116-14 | chr15:25081121 C>A | 3'Flank (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- STAT5B | c.*1534T>C | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- ZNF148 | c.*872T>G | 3'UTR (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
